Surgical pathology report (de-identified scan), TCGA case TCGA-BJ-A291, project TCGA-THCA (Thyroid Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-BJ-A291-01A (Primary Tumor).

PATIENT HISTORY:

CHIEF COMPLAINT/PRE-OP/POST-OP DIAGNOSIS: Thyroid cancer.

PROCEDURE: Total thyroidectomy.

SPECIFIC CLINICAL QUESTION: Not answered.

OUTSIDE TISSUE DIAGNOSIS: Not answered.

PRIOR MALIGNANCY: Not answered.

CHEMORADIATION: Not answered.

ORGAN TRANSPLANT: Not answered.

IMMUNOSUPPRESSION: Not answered.

OTHER DISEASES: Not answered.

Collection Date: _____

FINAL DIAGNOSIS:**PART 1: THYROID GLAND, TOTAL THYROIDECTOMY (27 GRAMS) -**

- A. TWO (2) FOCI OF PAPILLARY CARCINOMA (0.3 CM AND 1.5 CM), ONCOCYTIC VARIANT, RIGHT LOBE (see comment).
- B. NODULAR THYROID.
- C. CHRONIC LYMPHOCYTIC THYROIDITIS.
- D. THREE (3) BENIGN LYMPH NODES (0/3) (ONE ATTACHED TO RIGHT LOBE AND TWO ATTACHED TO ISTHMUS).
- E. NO PARATHYROIDS ARE SEEN.
- F. PATHOLOGICAL STAGE: pT1 N0 MX.

PART 2: LYMPH NODES, CENTRAL COMPARTMENT, EXCISION -

- A. SIX (6) BENIGN LYMPH NODES (0/6).
- B. THYROID NODULE WITH CHRONIC LYMPHOCYTIC THYROIDITIS AND FIBROSIS.

COMMENT:

As indicated above, we have demonstrated two foci of papillary carcinoma in the right lobe which measure 0.3 cm (follicular variant) and 1.5 cm. (encapsulated with oncocytic features; no capsular invasion is seen) Both of these foci are confined to the thyroid gland with no angiolymphatic or extrathyroidal extension. Margins are free of tumor.

Few of the lymphoid follicles associated with the lymphocytic thyroiditis show atypical features, hence the hematopathologists were consulted for their opinion. The general consensus is that the follicles are reactive.

Molecular studies are being performed on both the foci and the results will follow in an addendum.

CASE SYNOPSIS:**SYNOPTIC DATA - PRIMARY THYROID TUMORS**

SPECIMEN TYPE: Total Thyroidectomy
TUMOR SITE: Right Lobe
TUMOR FOCALITY: Multifocal
TUMOR SIZE (largest nodule): Greatest Dimension: 1.5 cm
HISTOLOGIC TYPE: Papillary carcinoma
PATHOLOGIC STAGING (pTNM): pT1
pN0
Number of regional lymph nodes examined: 9
Number of regional lymph nodes involved: 0
pMX
MARGINS: Margins uninvolved by carcinoma
VENOUS/LYMPHATIC (LARGE/SMALL VESSEL) INVASION (V/L): Absent
ADDITIONAL PATHOLOGIC FINDINGS: Nodular goiter
Thyroiditis

ICD-0-3

Carcinoma, papillary, follicular variant
8340/3

Site: Thyroid, NOS C73.9

hw
5/25/11

Source: NCI Genomic Data Commons file 8ac9fadb-d2d5-4ce0-b9be-8a9bfd20c0f6 (TCGA-BJ-A291.71C89B49-FA32-4831-9E62-7228751405F1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).